Somatic mutation profile of tumor specimen TCGA-2Y-A9H9-01A (aliquot TCGA-2Y-A9H9-01A-21D-A38X-10) from TCGA case TCGA-2Y-A9H9, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 70.3 years (25,670 days).
Specimen TCGA-2Y-A9H9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ba8117b-464e-4c1e-9742-95018642bbc6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2Y-A9H9-10A (Blood Derived Normal), aliquot TCGA-2Y-A9H9-10A-01D-A38X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df386e2b-b9f0-4bcb-b1ee-68251b6ffa79

The open-access MAF lists 134 somatic variants for this specimen: 107 protein-altering or splice-affecting, 25 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 87, Silent 25, Nonsense Mutation 9, Frame Shift Del 6, Splice Region 2, In Frame Del 2, Nonstop Mutation 1, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A5 | c.3206G>T p.G1069V | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs281874712, CM107309, CM145029, COSV100088792; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- AACS | c.1798G>T p.V600F | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.59); catalogued as COSV99908185; called by muse, mutect2, varscan2
- ABCA7 | c.1765G>A p.A589T | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as rs766735311, COSV99566331; called by muse, mutect2, varscan2
- ADAM28 | c.1924G>T p.E642* | Nonsense Mutation (SNP) | VAF 38/52 reads (73%) | catalogued as COSV99739295; called by muse, mutect2, varscan2
- ANKRD44 | c.1802G>A p.R601H | Missense Mutation (SNP) | VAF 57/126 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as rs374386037; called by muse, mutect2, varscan2
- ATP13A1 | c.2146G>A p.V716I | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as rs1364342483, COSV99366401; called by muse, mutect2
- ATP2B4 | c.3100T>C p.F1034L | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as rs147064623; called by muse, mutect2, varscan2
- C7orf25 | c.1229C>G p.P410R | Missense Mutation (SNP) | VAF 69/188 reads (37%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as COSV100623652; called by muse, mutect2, varscan2
- CDH11 | c.642A>G p.T214= | Splice Region (SNP) | VAF 23/53 reads (43%) | catalogued as COSV99219253; called by muse, mutect2, varscan2
- CDKN3 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 144/342 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); catalogued as COSV99369923; called by muse, varscan2
- CERS2 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54978124; called by muse, mutect2
- CLEC1B | c.382C>G p.Q128E | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV100046136; called by muse, mutect2, varscan2
- CSMD3 | c.9071A>G p.K3024R (on ENST00000297405 / NM_001363185.1; = p.K2855R on NM_052900.3) | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99841377; called by muse, mutect2, varscan2
- DCAF12L2 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 79/98 reads (81%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.454); catalogued as rs767452980, COSV63580230, COSV63583864; called by muse, mutect2, varscan2
- DCAF4L2 | c.848A>T p.Q283L | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as COSV100151105; called by muse, mutect2, varscan2
- DDB1 | c.341G>T p.R114L | Missense Mutation (SNP) | VAF 51/101 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV100074745; called by muse, mutect2, varscan2
- DNAH7 | c.5974A>G p.N1992D | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.207); catalogued as COSV100416376; called by muse, mutect2, varscan2
- F8 | c.1351A>G p.T451A | Missense Mutation (SNP) | VAF 65/75 reads (87%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100811689; called by muse, mutect2, varscan2
- FAM47A | c.1994A>T p.E665V | Missense Mutation (SNP) | VAF 67/78 reads (86%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV100649990; called by muse, mutect2, varscan2
- FASN | c.3408G>T p.E1136D | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV100148101; called by muse, mutect2, varscan2
- FAT2 | c.2645A>G p.D882G | Missense Mutation (SNP) | VAF 91/189 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99943655; called by muse, mutect2, varscan2
- FAT3 | c.5077A>C p.I1693L | Missense Mutation (SNP) | VAF 59/140 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV99968210; called by muse, mutect2, varscan2
- FLG | c.6470C>T p.S2157L | Missense Mutation (SNP) | VAF 73/198 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs761306814, COSV64237796; called by muse, mutect2, varscan2
- GIN1 | c.157G>T p.V53F | Missense Mutation (SNP) | VAF 72/174 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV67537774; called by muse, mutect2, varscan2
- GPR137 | c.895C>T p.R299W | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV100464389; called by muse, mutect2
- GPR139 | c.391T>C p.C131R | Missense Mutation (SNP) | VAF 69/143 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV100429960; called by muse, mutect2, varscan2
- GPRC6A | c.1551A>G p.Q517= | Splice Region (SNP) | VAF 33/62 reads (53%) | catalogued as COSV100114570; called by muse, mutect2, varscan2
- H2AJ | c.356A>G p.K119R | Missense Mutation (SNP) | VAF 75/155 reads (48%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.312); catalogued as rs371368734; called by muse, mutect2, varscan2
- H4C7 | c.61A>G p.K21E | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV99769177; called by muse, mutect2, varscan2
- HADHB | c.622G>T p.A208S | Missense Mutation (SNP) | VAF 53/105 reads (50%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV100502094; called by muse, mutect2, varscan2
- HECW2 | c.887A>G p.D296G | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as COSV99648077; called by muse, mutect2, varscan2
- HHIPL2 | c.931G>A p.V311I | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.609); catalogued as COSV100596993; called by muse, mutect2, varscan2
- INPP4B | c.491T>C p.V164A | Missense Mutation (SNP) | VAF 141/327 reads (43%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs753433691, COSV99525676; called by muse, mutect2, varscan2
- INPP5F | c.1790A>C p.E597A | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV100740282; called by muse, mutect2, varscan2
- ITGA1 | c.2897A>G p.N966S | Missense Mutation (SNP) | VAF 182/487 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs539547486, COSV99251779; called by muse, mutect2, varscan2
- KCNH8 | c.634T>C p.F212L | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.566); catalogued as COSV100110573; called by muse, mutect2, varscan2
- KIAA1586 | c.1441G>C p.G481R | Missense Mutation (SNP) | VAF 90/214 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100875373; called by muse, mutect2, varscan2
- KRTAP11-1 | c.452A>G p.Y151C | Missense Mutation (SNP) | VAF 69/160 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.145); catalogued as rs1485939635, COSV100190748; called by muse, mutect2, varscan2
- LSR | c.1328G>T p.R443L (on ENST00000361790; = p.R424L on NM_015925.6) | Missense Mutation (SNP) | VAF 63/137 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); catalogued as COSV99723456; called by muse, mutect2, varscan2
- MAGEC2 | c.834G>T p.W278C | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV99909764; called by muse, mutect2, varscan2
- MAP1A | c.1672C>A p.P558T | Missense Mutation (SNP) | VAF 78/170 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100288273, COSV100288972; called by muse, mutect2, varscan2
- MAP4 | c.2899C>T p.R967* | Nonsense Mutation (SNP) | VAF 54/120 reads (45%) | catalogued as COSV99275844; called by muse, mutect2, varscan2
- MARCHF10 | c.1217A>T p.K406I | Missense Mutation (SNP) | VAF 71/124 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as rs1463598935, COSV100248400; called by muse, mutect2, varscan2
- MDN1 | c.8530G>C p.D2844H | Missense Mutation (SNP) | VAF 64/163 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.496); catalogued as COSV101021595; called by muse, mutect2, varscan2
- MEGF11 | c.610T>A p.C204S | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99988615; called by muse, mutect2, varscan2
- MFSD11 | c.1175A>T p.K392M | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV100334095, COSV60625772; called by muse, mutect2, varscan2
- MKRN3 | c.1246T>C p.C416R | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100091411; called by muse, mutect2, varscan2
- MOS | c.678G>T p.L226F | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100322944; called by muse, mutect2, varscan2
- MRPS9 | c.476A>G p.Y159C | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764645292, COSV99306247, COSV99306295; called by muse, mutect2, varscan2
- MRS2 | c.119G>T p.G40V | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.281); catalogued as COSV99219054; called by muse, mutect2, varscan2
- MSH6 | c.433A>T p.K145* | Nonsense Mutation (SNP) | VAF 68/156 reads (44%) | catalogued as COSV99316482; called by muse, mutect2, varscan2
- MST1R | c.2854G>A p.G952R | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.073); catalogued as rs754281140, COSV99619236; called by muse, mutect2, varscan2
- MYO9A | c.2312G>A p.R771Q | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as rs770800325, COSV100613955, COSV61849453; called by muse, mutect2, varscan2
- NALCN | c.1001A>T p.Q334L | Missense Mutation (SNP) | VAF 65/145 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV99216553; called by muse, varscan2
- NCOA7 | c.1702G>T p.G568C | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV57653656, COSV99997399; called by muse, mutect2, varscan2
- NLRP7 | c.1730A>G p.E577G | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100053067; called by muse, mutect2, varscan2
- NOL4 | c.1030C>T p.R344* | Nonsense Mutation (SNP) | VAF 25/63 reads (40%) | catalogued as rs1387546446, COSV52346444, COSV99307661; called by muse, mutect2, varscan2
- NRG1 | c.946A>C p.N316H (on ENST00000405005 / NM_013964.5; = p.N321H on NM_013956.5) | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99828830; called by muse, mutect2, varscan2
- NSG1 | c.286T>A p.C96S | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV101207954; called by muse, mutect2, varscan2
- OR6N2 | c.953G>C p.*318Sext*? | Nonstop Mutation (SNP) | VAF 29/85 reads (34%) | catalogued as COSV100210301; called by muse, mutect2, varscan2
- PARD6B | c.104C>A p.S35* | Nonsense Mutation (SNP) | VAF 18/174 reads (10%) | catalogued as COSV100860002; called by muse, mutect2
- PCDH12 | c.2213C>A p.S738Y | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV51520581, COSV99190994; called by muse, mutect2
- PDCL3 | c.292T>A p.S98T | Missense Mutation (SNP) | VAF 80/184 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.072); catalogued as rs777545241, COSV99959631; called by muse, mutect2, varscan2
- PDE10A | c.1027C>A p.Q343K | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.973); catalogued as COSV63095681; called by muse, mutect2, varscan2
- PKD2L2 | c.803C>A p.S268Y | Missense Mutation (SNP) | VAF 74/163 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99296524; called by muse, mutect2, varscan2
- PLOD3 | c.1287G>T p.W429C | Missense Mutation (SNP) | VAF 129/215 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99778155; called by muse, mutect2, varscan2
- POLG | c.2330G>A p.G777D | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99174936; called by muse, mutect2
- POLR3B | c.3343C>G p.Q1115E | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99942975, COSV99943685; called by muse, mutect2, varscan2
- PRSS23 | c.473C>T p.T158M | Missense Mutation (SNP) | VAF 72/184 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200816081, COSV99722506; called by muse, mutect2, varscan2
- PRUNE2 | c.2755T>C p.W919R | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100944909; called by muse, mutect2, varscan2
- PUS7L | c.670G>T p.A224S | Missense Mutation (SNP) | VAF 17/219 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100786576; called by muse, mutect2
- RAPH1 | c.3367A>C p.T1123P | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99864126; called by muse, mutect2, varscan2
- RBM18 | c.329G>T p.R110I | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.222); catalogued as COSV101313789; called by muse, mutect2, varscan2
- RNF148 | c.665C>A p.T222N | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV100411677; called by muse, mutect2, varscan2
- RNF168 | c.1231T>C p.S411P | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV100535042; called by muse, mutect2
- SCN7A | c.4324G>T p.A1442S | Missense Mutation (SNP) | VAF 156/373 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV101313309; called by muse, mutect2, varscan2
- SEMA3C | c.1816C>T p.Q606* | Nonsense Mutation (SNP) | VAF 36/72 reads (50%) | catalogued as rs557931063, COSV99543440; called by muse, mutect2, varscan2
- SIRPD | c.591A>C p.K197N | Missense Mutation (SNP) | VAF 26/58 reads (45%) | PolyPhen benign (0.39); catalogued as COSV101064969, COSV67547163; called by muse, mutect2, varscan2
- SLC17A2 | c.791T>A p.V264D | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV99614716; called by muse, mutect2, varscan2
- SLC52A1 | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 53/73 reads (73%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs370188723; called by muse, mutect2, varscan2
- SLC8A1 | c.1438A>T p.I480L | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.77); catalogued as COSV100246881; called by muse, mutect2, varscan2
- SLCO4C1 | c.592G>T p.E198* | Nonsense Mutation (SNP) | VAF 14/246 reads (6%) | catalogued as COSV60518129; called by muse, mutect2
- SMAD3 | c.362G>T p.C121F | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100529285; called by muse, mutect2
- SPAG8 | c.574C>T p.H192Y | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.131); catalogued as rs571991371, COSV99428100; called by muse, mutect2, varscan2
- TAF1D | c.445A>G p.I149V | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.826); catalogued as COSV100127023; called by muse, mutect2, varscan2
- TBC1D10A | c.985G>T p.E329* | Nonsense Mutation (SNP) | VAF 42/88 reads (48%) | catalogued as rs770050410, COSV99304781; called by muse, mutect2, varscan2
- TDP2 | c.953T>A p.I318K | Missense Mutation (SNP) | VAF 138/214 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100593749; called by muse, mutect2, varscan2
- TLK2 | c.2053C>T p.Q685* (on ENST00000326270 / NM_001284333.2; = p.Q663* on NM_006852.6 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 90/323 reads (28%) | catalogued as COSV100409412; called by muse, mutect2, varscan2
- TMEM108 | c.130G>T p.G44C | Missense Mutation (SNP) | VAF 75/170 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV100419260; called by muse, mutect2, varscan2
- TP53RK | c.547G>C p.D183H | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100927776, COSV64508992; called by muse, mutect2, varscan2
- TTN | c.81784T>G p.S27262A (on ENST00000591111; = p.S19838A on NM_003319.4) | Missense Mutation (SNP) | VAF 30/154 reads (19%) | PolyPhen benign (0); catalogued as COSV100621771; called by muse, mutect2, varscan2
- UPF3B | c.674_677del p.R225Kfs*22 | Frame Shift Del (DEL) | VAF 52/70 reads (74%) | catalogued as rs794727881; called by pindel, varscan2
- YTHDC1 | c.1474T>C p.F492L (on ENST00000344157 / NM_001031732.4; = p.F474L on NM_133370.4) | Missense Mutation (SNP) | VAF 111/240 reads (46%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as COSV100704809; called by muse, mutect2, varscan2
- ZNF10 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.071); catalogued as COSV99940093; called by muse, mutect2, varscan2
- ZNF334 | c.527T>G p.L176W | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.427); catalogued as COSV100749149; called by muse, mutect2, varscan2
- ZNF467 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1341285559, COSV57373354; called by muse, mutect2
- ZNF658 | c.880A>G p.M294V | Missense Mutation (SNP) | VAF 70/99 reads (71%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs767254486; called by muse, mutect2, varscan2
- ZNF799 | c.758A>G p.Y253C | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs755772439, COSV101345282; called by muse, mutect2, varscan2
- ZNF823 | c.1703G>A p.R568H | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); catalogued as rs373947909; called by muse, mutect2, varscan2
- ZNF91 | c.1903T>C p.C635R | Missense Mutation (SNP) | VAF 75/161 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs996602124, COSV100323213; called by muse, mutect2, varscan2
- ADGRB1 | c.531del p.N178Tfs*59 | Frame Shift Del (DEL) | VAF 21/65 reads (32%) | called by mutect2, pindel, varscan2
- EFNB2 | c.47del p.L16* | Frame Shift Del (DEL) | VAF 47/118 reads (40%) | called by mutect2, pindel, varscan2
- FIGNL2 | c.1744del p.E582Nfs*108 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- KRTAP21-2 | c.128_151del p.Y43_G50del | In Frame Del (DEL) | VAF 15/52 reads (29%) | called by pindel, varscan2
- OR11H6 | c.453del p.S152Pfs*3 | Frame Shift Del (DEL) | VAF 34/87 reads (39%) | called by mutect2, pindel, varscan2
- USP8 | c.3012_3014del p.P1005del | In Frame Del (DEL) | VAF 23/100 reads (23%) | called by pindel, varscan2
- ZBTB9 | c.1164_1165del p.C388Wfs*11 | Frame Shift Del (DEL) | VAF 34/109 reads (31%) | called by pindel, varscan2
- ADAMTS20 | c.1971T>C p.Y657= | Silent (SNP) | VAF 45/120 reads (38%) | catalogued as COSV101239867; called by muse, mutect2, varscan2
- CAGE1 | c.663C>T p.S221= (on ENST00000512086; = p.S85= on NM_205864.3) | Silent (SNP) | VAF 96/210 reads (46%) | catalogued as COSV99699948; called by muse, mutect2
- CLOCK | c.1968T>G p.T656= | Silent (SNP) | VAF 53/123 reads (43%) | catalogued as COSV100011891; called by muse, mutect2, varscan2
- CNTLN | c.2199A>G p.Q733= | Silent (SNP) | VAF 155/375 reads (41%) | catalogued as rs1341551114, COSV99265010; called by muse, mutect2, varscan2
- CTC1 | c.690A>C p.L230= | Silent (SNP) | VAF 34/49 reads (69%) | catalogued as COSV100236617; called by muse, mutect2, varscan2
- CYLC2 | c.612A>T p.T204= | Silent (SNP) | VAF 135/183 reads (74%) | catalogued as COSV100872510; called by muse, mutect2, varscan2
- DPRX | c.549T>C p.C183= | Silent (SNP) | VAF 42/104 reads (40%) | catalogued as COSV100934106; called by muse, mutect2, varscan2
- EPHA8 | c.411A>T p.T137= | Silent (SNP) | VAF 92/208 reads (44%) | catalogued as COSV99385290; called by muse, mutect2, varscan2
- MAG | c.690C>T p.G230= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV100727970; called by muse, mutect2
- MCM3AP | c.5703C>G p.P1901= | Silent (SNP) | VAF 28/62 reads (45%) | catalogued as COSV99387249; called by muse, mutect2, varscan2
- MRPS18B | c.84C>T p.P28= | Silent (SNP) | VAF 32/77 reads (42%) | catalogued as COSV99457786, COSV99457836; called by muse, mutect2, varscan2
- MTCL1 | c.1452A>G p.R484= (on ENST00000306329 / NM_001378206.1; = p.R124= on NM_015210.4) | Silent (SNP) | VAF 33/95 reads (35%) | catalogued as COSV100095204; called by muse, mutect2, varscan2
- MYO18B | c.3741C>T p.F1247= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as COSV59150355; called by muse, mutect2, varscan2
- NCOA2 | c.3939A>G p.P1313= | Silent (SNP) | VAF 82/126 reads (65%) | catalogued as COSV99144975; called by muse, mutect2, varscan2
- NEK6 | c.531C>T p.N177= | Silent (SNP) | VAF 23/27 reads (85%) | catalogued as rs553709380, COSV100207093, COSV57216873; called by muse, mutect2, varscan2
- NLRP12 | c.694C>T p.L232= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV100145553; called by muse, mutect2, varscan2
- OSM | c.711C>T p.P237= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as rs771721935, COSV99304260; called by muse, mutect2, varscan2
- PDZD3 | c.1579C>T p.L527= (on ENST00000531114; = p.L447= on NM_024791.4) | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV100501491; called by muse, mutect2, varscan2
- RHOF | c.387C>T p.I129= | Silent (SNP) | VAF 43/111 reads (39%) | catalogued as rs760874745, COSV99932318; called by muse, mutect2, varscan2
- SBNO2 | c.1720C>T p.L574= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100684807; called by muse, mutect2, varscan2
- SCAMP3 | c.552C>T p.A184= | Silent (SNP) | VAF 232/361 reads (64%) | catalogued as COSV100226835; called by muse, varscan2
- TYSND1 | c.549C>G p.G183= | Silent (SNP) | VAF 50/111 reads (45%) | catalogued as COSV99751988; called by muse, mutect2, varscan2
- ZDBF2 | c.1872A>G p.A624= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as COSV100985178; called by muse, mutect2, varscan2
- ZNF780B | c.2088C>G p.P696= | Silent (SNP) | VAF 49/118 reads (42%) | catalogued as COSV99665942; called by muse, mutect2, varscan2
- ZNF831 | c.642G>T p.L214= | Silent (SNP) | VAF 39/95 reads (41%) | catalogued as COSV100926136; called by muse, mutect2, varscan2
- CBLL1 | c.-1C>G | 5'UTR (SNP) | VAF 94/229 reads (41%) | catalogued as COSV99755816; called by muse, mutect2, varscan2
- ST8SIA2 | chr15:92472288 C>T | 3'Flank (SNP) | VAF 86/183 reads (47%) | catalogued as rs778203236; called by muse, mutect2, varscan2
